Gene-level copy-number profile of tumor specimen C3L-00011-01 from CPTAC case C3L-00011, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.8 years (23,307 days).
Specimen C3L-00011-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05c877d6-445e-4d05-bdfc-2a96cd87ff12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00011-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/4b561a58-632d-4dcd-bf2a-88d1b3a883d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 13,911; copy number 2: 42,409; copy number 3: 1,972.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr9:20,331,446–26,947,242, 94 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:26,955,780–27,005,672, 2 genes (within-gene range 0–1): IFT74-AS1, LRRC19.
- chr9:132,725,578–132,946,874, 4 genes (within-gene range 0–1): AK8, AL445645.1, SPACA9, TSC1.
- chr9:132,945,707–132,945,771, 1 gene (within-gene range 0–1): MIR548AW.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,567. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
